Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GI, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GI-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY SUPPLEMENTARY REPORT

SUPPLEMENTARY REPORT

Tissue was sent to the
rearrangement. The results are as follows:

for evaluation for IgH

"Procedure:

Specimen TISSUE
DNA IgH Rearrangement See below

The laboratory received paraffin fixed sections . DNA was prepared from this sample and amplified using primers for the immunoglobulin heavy chain (IgH).

No monoclonal B-CELL (IgH) population was detected."

The prominent marginal/mantle zone is interpreted as marginal/mantle zone hyperplasia.

SUPPLEMENTARY SUMMARY

RIGHT AXILLARY DISSECTION:

- **METASTATIC MELANOMA** in one of twenty one lymph nodes (1/31)
- **No extranodal extension is seen.**

REPORTED BY: Dr

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary CT77.3
4/10/11

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Background: metastatic melanoma right axilla biopsy proven.
Right axillary dissection specimen for tumour bank.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar/ Pathologist:
Two slices from the largest lymph node taken for tumour banking by Dr .

MACROSCOPIC DESCRIPTION

(Dr

"RIGHT AXILLARY DISSECTION". The specimen consists of fibrofatty tissue 120 x 110 x 40mm with attached skeletal muscle 85 x 65 x 20mm. **The largest lymph node measures 65mm across.** Serial sectioning of the skeletal muscle is unremarkable.

- A. Representative section of the largest node (grossly appears involved by the tumour).
B-C. Representative sections from two larger nodes grossly appear involved by the tumour. . not involved microscopically therefore remainder of both nodes submitted in X-AA).
D-Q. One node in each block bisected.

ICDPA Discrepancy		X

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

R-U. Five nodes in each block.
V. Six nodes.
W. Representative section of the skeletal muscle.
Additional sections:
X-Z Remainder of one of the enlarged nodes
AA Remainder of the other of the enlarged nodes
AB-AC Additional sections of involved lymph node to assess for extranodal extension.

MICROSCOPIC REPORT

"RIGHT AXILLARY DISSECTION". Microscopy confirms the presence of metastatic melanoma in the macroscopically involved lymph node (block A). The tumour is composed of spindled and epithelial cells with moderate to abundant eosinophilic cytoplasm and prominent nucleoli. Foci of necrosis are seen. The tumour stains positively in immunostains for S100, HMB45 and Melan A, supporting the diagnosis of melanoma. The deposit partially replaces the lymph node and is intraparenchymal in location. No extranodal extension is seen in the sections examined (including additional sections taken specifically to assess for extranodal extension).

An additional 30 lymph nodes are identified and no further deposits of metastatic melanoma are seen.

Several of the uninvolved lymph nodes are enlarged and show a prominent marginal/mantle zone (e.g. blocks B and C). Occasional monocytoïd-type cells are seen. Scattered single histiocytes are identified. No pericapsular extension is seen. The sinuses are preserved. Scattered reactive follicles are present while other follicles appear regressed. Immunohistochemical studies for lymphoid markers have been performed and confirm an expansion of the marginal/mantle zone. The follicles show a reactive pattern in a bcl-2 stain. No aberrant expression of CD5 or CD43 by B-lymphocytes is seen (CD20, CD79a). A cyclin D1 stain is negative. The appearance is a little unusual and is favoured to be marginal/mantle zone hyperplasia rather than marginal zone lymphoma.

COMMENT

Metastatic melanoma is seen in one lymph node. Other nodes are enlarged and show expansion of the marginal/mantle zone. This is favoured to be a reactive hyperplasia but PCR has been requested to exclude the possibility of a marginal zone lymphoma. A supplementary report will be issued with the result.

SUMMARY

RIGHT AXILLARY DISSECTION:

- METASTATIC MELANOMA in one of twenty one lymph nodes (1/31)
- No extranodal extension is seen.
- Several other nodes are enlarged and show a prominent marginal/mantle zone with features favouring marginal/mantle zone hyperplasia (see comment).

REPORTED BY: Dr

Source: NCI Genomic Data Commons file 350913a7-e7d5-4978-881f-0e8a903eca78 (TCGA-EE-A2GI.99CDD070-FBAF-4310-9022-7F3DFD9E7043.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).